Somatic mutation profile of tumor specimen 0DOV9H from CCDI case PBCCJS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.6 years (1,326 days).
Specimen 0DOV9H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb371e96-43ad-48b9-a14e-42b90876c9fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOV8H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bddd785e-7bfe-463c-ad47-44aba816b052

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC4A10 | c.1240G>A p.V414I (on ENST00000446997 / NM_001354461.2; = p.V384I on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 402/928 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV55792938; called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 32/1087 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- JAG1 | c.2426C>T p.A809V | Missense Mutation (SNP) | VAF 20/707 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2
- KAZN | c.1203C>T p.L401= | Silent (SNP) | VAF 372/775 reads (48%) | catalogued as rs757094991, COSV100747911; called by muse, mutect2, varscan2
- GATD1 | c.544+91G>A | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
